Somatic mutation profile of tumor specimen TARGET-15-SJMPAL017978-09A.2 (aliquot TARGET-15-SJMPAL017978-09A.2-01D) from TARGET case TARGET-15-SJMPAL017978, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (730 days).
Specimen TARGET-15-SJMPAL017978-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6669fcd8-2e39-4500-87da-a90323552d6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL017978-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL017978-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90789f3b-522c-4774-b5d8-3f7caca7cbfd

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM135B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200240655; called by muse, mutect2, varscan2
- GLB1L2 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs147686340; called by muse, mutect2, varscan2
- AMBN | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- AMOT | c.2827G>T p.A943S (on ENST00000371959 / NM_001113490.1; = p.A534S on NM_133265.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); called by mutect2, varscan2
- C10orf90 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.219); called by muse, mutect2
- DDX21 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- HS1BP3 | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- MMRN2 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PKP4 | c.2870C>A p.A957D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, varscan2
- SEC31A | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC16A4 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- SLCO1C1 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TTF1 | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- XXYLT1 | c.994G>T p.D332Y | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZKSCAN2 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, varscan2
- BMP2 | c.906C>T p.Y302= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs374065751; called by muse, mutect2, varscan2
- EEF1D | c.765G>T p.G255= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- MARCHF10 | c.1221C>T p.S407= | Silent (SNP) | VAF 51/100 reads (51%) | catalogued as rs777152212; called by muse, mutect2, varscan2
- MRGBP | c.558C>A p.V186= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- MROH2A | c.2355C>T p.C785= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs770274993; called by muse, mutect2, varscan2
- ZNF512B | c.153G>T p.V51= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- CDK2AP1 | c.*11G>T | 3'UTR (SNP) | VAF 4/29 reads (14%) | called by mutect2, varscan2
